Gene-level copy-number profile of tumor specimen TCGA-N5-A4RM-01A from TCGA case TCGA-N5-A4RM, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Age at diagnosis: 62.7 years (22,886 days).
Specimen TCGA-N5-A4RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.94f63eed-5baf-4479-9c1f-f1bed2052aab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A4RM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f3c98477-61f7-4fac-ad3e-676ff7a07f6a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 21,352; copy number 2: 34,458; copy number 3: 2,995; copy number 4: 826; copy number 5: 131.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A4RM-01A-11D-A28Q-01): tumor purity 0.96, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr3:116,850,277–117,027,039, 5 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr4:182,143,987–182,803,024, 4 genes (within-gene range 0–2): TENM3, AC108142.1, MIR1305, RNU2-34P.
- chr5:165,129,307–166,382,599, 9 genes: AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1.
- chr14:42,259,731–42,703,655, 4 genes (within-gene range 0–1): AL445074.1, AL442163.1, AL450442.1, AL442163.2.
- chr15:77,420,412–77,608,888, 4 genes: HMG20A, AC090984.1, AC046168.1, AC046168.2.
- chr15:77,641,764–77,668,074, 2 genes: LINGO1-AS1, LINGO1-AS2.
- chr17:30,956,280–31,538,211, 22 genes (within-gene range 0–1): AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 131 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:30,163,206–31,112,575, 63 genes, copy number 5 (broad region; genes not listed).
- chr19:44,326,555–45,602,212, 65 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:48,821,688–49,038,602, 3 genes, copy number 5: AL133342.1, ARFGEF2, SNAP23P1.

Autosomal genes at a single copy (total copy number 1): 18,943. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
